MMRF case MMRF_1646 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/be90cdd9-b06b-4121-b02c-8ce0bfcc9f9a

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Dead; Days to death: 23 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.9 years (30,281 days); ISS stage: III; Days to last known disease status: 23 days; Days to last follow up: 23 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 15 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 23 days.

Follow-up (2 entries)
- Days to follow up: -5 days; ECOG performance status: 3.
- Follow-up contact recording only the day: day 23.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Platelets 85 ×10⁹/L.
- Immunoglobulin A 0.79 g/L.
- Hemoglobin 4.65 mmol/L.
- Leukocytes 3.9 ×10⁹/L.
- Blood Urea Nitrogen 38.6 mmol/L.
- Glucose 9.68 mmol/L.
- Lactate Dehydrogenase 3.23 µkat/L.
- Immunoglobulin G 17 g/L.
- Calcium 2.08 mmol/L.
- Albumin 34 g/L.
- Beta 2 Microglobulin 16.6 µg/mL.
- Serum Free Immunoglobulin Light Chain, Kappa 7.27 mg/dL.
- Immunoglobulin M 0.4 g/L.
- Absolute Neutrophil 3 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Lambda 5.12 mg/dL.
- Creatinine 398 µmol/L.
- Total Protein 6.6 g/dL.
- M Protein 1.04 g/dL.

Other clinical attributes
- Day -5: Weight: 89 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1646_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1646_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
